Somatic mutation profile of tumor specimen 0DSWZB from CCDI case PBCIJZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Atypical teratoid/rhabdoid tumor; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 2.0 years (730 days).
Specimen 0DSWZB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3c384c0-c5f8-4d11-8fe8-11d87fc61394.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSWZ1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/22f3eccd-525d-49c0-b5a3-45a08a6a8574

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PLXNA3 | c.2717C>T p.P906L | Missense Mutation (SNP) | VAF 216/576 reads (38%) | SIFT tolerated (0.47); PolyPhen probably damaging (1); catalogued as rs782379214; called by muse, mutect2, varscan2
- ZDBF2 | c.5024G>A p.R1675Q | Missense Mutation (SNP) | VAF 36/679 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs749703720, COSV65624340; called by muse, mutect2
- FLG | c.8824C>A p.H2942N | Missense Mutation (SNP) | VAF 62/423 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KMT2B | c.6696G>A p.W2232* | Nonsense Mutation (SNP) | VAF 91/242 reads (38%) | called by muse, mutect2, varscan2
- ILF2 | c.819G>A p.Q273= | Silent (SNP) | VAF 16/426 reads (4%) | called by muse, mutect2
